Somatic mutation profile of tumor specimen ALCH-B2MS-TTP1-A (aliquot ALCH-B2MS-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2MS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.3 years (22,392 days).
Specimen ALCH-B2MS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29d0eb2a-dd66-4771-b79e-9479b7f8e3b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MS-NB1-A (Blood Derived Normal), aliquot ALCH-B2MS-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd866311-0b5f-480a-8741-696344d131c6

The open-access MAF lists 125 somatic variants for this specimen: 89 protein-altering or splice-affecting, 23 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 23, Nonsense Mutation 8, Intron 5, 5'UTR 4, Splice Site 4, Frame Shift Del 2, RNA 2, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.1386G>C p.L462F | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99176233; called by muse, mutect2, varscan2
- C1QC | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1373636175, COSV65889544; called by muse, mutect2
- CASP5 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 77/754 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52828233; called by muse, mutect2, varscan2
- CCDC168 | c.12560C>A p.P4187Q | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.864); catalogued as rs1403157275; called by muse, mutect2
- CIDEA | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs749676549; called by muse, mutect2, varscan2
- CR1L | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 52/624 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1305199861, COSV54327789; called by muse, mutect2
- CST8 | c.275G>C p.R92P | Missense Mutation (SNP) | VAF 47/690 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55672000; called by muse, mutect2
- DCST1 | c.1352C>A p.S451* | Nonsense Mutation (SNP) | VAF 58/478 reads (12%) | catalogued as COSV55060337; called by muse, mutect2, varscan2
- DOK7 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs763936252; called by muse, mutect2
- DPP6 | c.1107G>T p.E369D (on ENST00000377770 / NM_001364500.2; = p.E307D on NM_001936.5) | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV59607901; called by muse, mutect2, varscan2
- DSTYK | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1242711305; called by muse, mutect2
- FMN1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.197); catalogued as rs972678254; called by muse, mutect2, varscan2
- GINS2 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs750348978; called by muse, mutect2, varscan2
- GOLGA6D | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 37/384 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1345368511, COSV71561408, COSV71561572; called by muse, mutect2, varscan2
- GPR35 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1166703389; called by muse, mutect2, varscan2
- GRIK4 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 61/493 reads (12%) | catalogued as rs1377111124, COSV70799410; called by muse, mutect2, varscan2
- GRM8 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 29/465 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs774000074, COSV58809610, COSV58825673; called by muse, mutect2
- GUCY2F | c.2954C>T p.S985L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768377831; called by muse, varscan2
- HCK | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 50/516 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780405467, COSV52941139; called by muse, mutect2, varscan2
- IL3 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | catalogued as rs373251020; called by muse, mutect2
- KCTD8 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1347768461; called by muse, mutect2
- KIAA0100 | c.248+1G>A p.X83_splice | Splice Site (SNP) | VAF 22/332 reads (7%) | catalogued as rs757261989, COSV55931874; called by muse, mutect2
- KMT2C | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 59/547 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs752277873; called by muse, mutect2, varscan2
- MISP | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 33/440 reads (8%) | catalogued as COSV53120260; called by muse, mutect2
- MRC1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 114/1039 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781931651; called by muse, mutect2, varscan2
- MXRA5 | c.6440G>A p.R2147H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54229047, COSV54244657; called by muse, mutect2, varscan2
- MYO18B | c.4604G>A p.R1535H | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757686311, COSV59130706; called by muse, mutect2
- NME7 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV63164711, COSV63167985; called by muse, mutect2
- NPEPPS | c.1789A>G p.M597V | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs1253735072; called by muse, mutect2
- NUP88 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV56708156; called by muse, mutect2, varscan2
- PCDHA4 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.592); catalogued as COSV100793400; called by muse, mutect2, varscan2
- PDE6C | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 120/970 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771237873; called by muse, mutect2, varscan2
- PIKFYVE | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 58/568 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1414178358, COSV52237080; called by muse, mutect2
- PRSS1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs141011596; called by muse, mutect2
- PXDNL | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100685516, COSV100687207; called by muse, mutect2, varscan2
- RAD52 | c.726-5T>C | Splice Region (SNP) | VAF 14/157 reads (9%) | catalogued as rs1161266813; called by muse, mutect2
- SAMD9L | c.2889G>C p.K963N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV59081181; called by muse, mutect2, varscan2
- SERINC4 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 68/660 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV51052007; called by muse, mutect2, varscan2
- SLC23A3 | c.1553G>A p.R518Q (on ENST00000409878 / NM_001144889.2; = p.R401Q on NM_144712.5) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373144689, COSV104404080; called by muse, mutect2, varscan2
- TEX36 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 56/488 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1051324928; called by muse, mutect2, varscan2
- TGFBR3 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 128/651 reads (20%) | catalogued as COSV99282366; called by muse, mutect2, varscan2
- UNC80 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 22/203 reads (11%) | catalogued as rs1274923045, COSV55911631; called by muse, mutect2, varscan2
- UVRAG | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs376553699; called by muse, mutect2, varscan2
- VCAN | c.9713G>A p.R3238H | Missense Mutation (SNP) | VAF 80/883 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138263053, COSV54120090; called by muse, mutect2
- ZNF205 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99530550; called by muse, mutect2
- ZNF595 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1198645120; called by muse, mutect2
- ABCA3 | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 180/672 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG2 | c.2999T>A p.M1000K (on ENST00000379869 / NM_001079858.3; = p.M997K on NM_005756.4) | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ANKRD53 | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 47/453 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ARFGAP2 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2
- C4orf50 | c.487G>A p.D163N (on ENST00000324058; = p.D1395N on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CASZ1 | c.1815del p.K606Rfs*80 | Frame Shift Del (DEL) | VAF 33/137 reads (24%) | called by mutect2, pindel, varscan2
- CDC20 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CHD8 | c.2705A>T p.Y902F (on ENST00000646647 / NM_001170629.2; = p.Y623F on NM_020920.4) | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CNTN5 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CNTN6 | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by mutect2, varscan2
- CRYBG3 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- DNAJC1 | c.624A>T p.E208D | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- DNAJC17 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 114/454 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DPY19L2 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUOX2 | c.-14-2A>T | Splice Site (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- EBF2 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 69/497 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GMNC | c.179-1G>C p.X60_splice | Splice Site (SNP) | VAF 67/275 reads (24%) | called by muse, mutect2, varscan2
- GOLGA4 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- HTT | c.4880C>G p.S1627C | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRTAP4-7 | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 55/509 reads (11%) | called by muse, varscan2
- LRP1 | c.4846A>G p.N1616D | Missense Mutation (SNP) | VAF 61/649 reads (9%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.971); called by muse, mutect2
- MCTP1 | c.721-2A>C p.X241_splice | Splice Site (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- MMP20 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 68/890 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- MTHFD2L | c.873C>G p.N291K (on ENST00000395759 / NM_001144978.2; = p.N233K on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/508 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- MTNR1B | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO7B | c.5194C>A p.Q1732K | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFATC2 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRSN1 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- OPLAH | c.1006A>G p.S336G | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OR10G8 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PDE4DIP | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 50/1502 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); called by muse, mutect2
- POLR2A | c.4021G>A p.V1341M | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SAMSN1 | c.1100T>A p.I367N | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SLC4A1 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC8A3 | c.2146G>A p.E716K (on ENST00000381269 / NM_183002.3; = p.E714K on NM_033262.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); called by muse, varscan2
- SLITRK2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- STYXL2 | c.3227del p.K1076Sfs*18 | Frame Shift Del (DEL) | VAF 56/570 reads (10%) | called by mutect2, pindel, varscan2
- TRPA1 | c.2122C>G p.L708V | Missense Mutation (SNP) | VAF 44/599 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.049); called by muse, mutect2
- TTN | c.38110C>A p.P12704T (on ENST00000591111; = p.P5280T on NM_003319.4) | Missense Mutation (SNP) | VAF 15/222 reads (7%) | PolyPhen possibly damaging (0.6); called by muse, mutect2
- UHRF1BP1L | c.3559G>A p.D1187N | Missense Mutation (SNP) | VAF 54/560 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- XIRP2 | c.6128A>G p.D2043G (on ENST00000628543; = p.D2218G on NM_152381.6) | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.265); called by muse, mutect2
- ZNF117 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF273 | c.907T>G p.S303A | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.109); called by muse, mutect2
- BICD2 | c.753C>T p.R251= | Silent (SNP) | VAF 102/778 reads (13%) | catalogued as rs533852054; ClinVar: likely benign; called by muse, mutect2, varscan2
- BICDL2 | c.1464C>T p.F488= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- CAD | c.1473C>T p.A491= | Silent (SNP) | VAF 20/275 reads (7%) | catalogued as rs770974703, COSV99255624; called by muse, mutect2
- CRB1 | c.2895C>T p.S965= | Silent (SNP) | VAF 79/376 reads (21%) | called by muse, mutect2, varscan2
- CRYBB1 | c.294G>A p.A98= | Silent (SNP) | VAF 56/513 reads (11%) | catalogued as rs760235124, COSV53233444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSAG3 | c.186C>T p.D62= | Silent (SNP) | VAF 119/1473 reads (8%) | catalogued as rs1463213424; called by muse, mutect2
- DCAKD | c.96C>T p.D32= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as rs1270607986; called by muse, mutect2, varscan2
- DNASE1L1 | c.324A>T p.T108= | Silent (SNP) | VAF 57/155 reads (37%) | called by muse, mutect2, varscan2
- FAM189A2 | c.819G>A p.S273= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV99975460; called by muse, mutect2, varscan2
- FGFR4 | c.477G>T p.L159= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- FSHR | c.66C>A p.I22= | Silent (SNP) | VAF 66/813 reads (8%) | catalogued as rs780626964; called by muse, mutect2
- GAS6 | c.1575C>T p.L525= | Silent (SNP) | VAF 19/249 reads (8%) | called by muse, mutect2
- GRM1 | c.2766G>A p.T922= | Silent (SNP) | VAF 137/1044 reads (13%) | catalogued as rs557241976; called by muse, mutect2, varscan2
- KLHL4 | c.222G>T p.L74= | Silent (SNP) | VAF 67/417 reads (16%) | called by muse, mutect2, varscan2
- MED22 | c.357G>T p.L119= | Silent (SNP) | VAF 64/476 reads (13%) | called by muse, mutect2, varscan2
- MYOD1 | c.411G>T p.S137= | Silent (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- OR4F21 | c.171C>A p.S57= | Silent (SNP) | VAF 99/669 reads (15%) | called by muse, mutect2, varscan2
- PDE4DIP | c.222T>A p.A74= | Silent (SNP) | VAF 52/1510 reads (3%) | called by muse, mutect2
- PTCRA | c.573C>T p.L191= | Silent (SNP) | VAF 30/419 reads (7%) | catalogued as rs1038771738; called by muse, mutect2
- TNN | c.3204G>C p.S1068= | Silent (SNP) | VAF 35/212 reads (17%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.3006C>T p.L1002= | Silent (SNP) | VAF 83/614 reads (14%) | called by muse, mutect2, varscan2
- USP9X | c.1275T>C p.A425= | Silent (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- ZNF469 | c.9966C>T p.F3322= (on ENST00000437464; = p.F3350= on NM_001367624.2) | Silent (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+9981G>T | Intron (SNP) | VAF 32/456 reads (7%) | called by muse, mutect2
- AL136982.4 | n.1597G>A | RNA (SNP) | VAF 40/880 reads (5%) | called by muse, mutect2
- AP1G2 | c.-60G>C | 5'UTR (SNP) | VAF 9/79 reads (11%) | catalogued as COSV58113041; called by muse, mutect2, varscan2
- CENPN | c.633+108G>C | Intron (SNP) | VAF 140/568 reads (25%) | called by muse, mutect2, varscan2
- CEP41 | c.*3026G>A | 3'UTR (SNP) | VAF 44/498 reads (9%) | called by muse, mutect2
- CPNE2 | c.-36+1269G>T | Intron (SNP) | VAF 42/556 reads (8%) | called by muse, mutect2
- IGFBP4 | c.-22C>T | 5'UTR (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- KIF5A | c.2910-11G>T | Intron (SNP) | VAF 77/707 reads (11%) | called by muse, mutect2, varscan2
- OR2L1P | n.629A>T | RNA (SNP) | VAF 45/393 reads (11%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49891302 G>A | 5'Flank (SNP) | VAF 96/761 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.-86G>A | 5'UTR (SNP) | VAF 82/249 reads (33%) | catalogued as rs947391953; called by muse, mutect2, varscan2
- SNCB | c.164-92T>A | Intron (SNP) | VAF 11/121 reads (9%) | called by muse, mutect2, varscan2
- SPSB4 | c.-5G>A | 5'UTR (SNP) | VAF 16/235 reads (7%) | called by muse, mutect2
